Somatic mutation profile of tumor specimen 0E1HF7 from CCDI case PBCWKG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1HF7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12f7291f-8850-42c7-a350-04812348a59d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HG6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e969e38-0f2d-45b3-af2f-11674c136c15

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, RNA 2, Nonsense Mutation 2, 3'UTR 2, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR3 | c.7859T>C p.L2620P | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1330352002; called by muse, mutect2, varscan2
- FBXO22 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs1477622312; called by muse, mutect2
- KCNJ12 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 62/583 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs538702652, COSV59168075; called by muse, mutect2, varscan2
- PROCR | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 285/385 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs145801152, COSV53825676; called by muse, mutect2, varscan2
- RET | c.3148C>T p.R1050* | Nonsense Mutation (SNP) | VAF 55/314 reads (18%) | catalogued as CM1110093; called by muse, mutect2, varscan2
- STOML2 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1564009325; called by muse, mutect2, varscan2
- TRIM39 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 55/418 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV100935913; called by muse, mutect2, varscan2
- MFSD4A | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 76/688 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35G6 | c.999_1001dup p.G334dup | In Frame Ins (INS) | VAF 65/518 reads (13%) | called by pindel, varscan2
- ZNF473 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 84/337 reads (25%) | called by muse, mutect2, varscan2
- LTBP1 | c.3987C>T p.S1329= (on ENST00000404816 / NM_206943.4; = p.S1003= on NM_000627.4) | Silent (SNP) | VAF 70/382 reads (18%) | catalogued as COSV55386635; called by muse, mutect2
- MFSD4A | c.297C>A p.I99= | Silent (SNP) | VAF 78/689 reads (11%) | catalogued as rs758083413; called by muse, mutect2, varscan2
- PCK1 | c.804G>T p.L268= | Silent (SNP) | VAF 68/286 reads (24%) | called by muse, mutect2, varscan2
- ZNF275 | c.951C>T p.G317= | Silent (SNP) | VAF 51/89 reads (57%) | called by muse, mutect2, varscan2
- COMT | c.-148G>A | 5'UTR (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- EME2 | c.*1663C>T | 3'UTR (SNP) | VAF 58/118 reads (49%) | catalogued as rs573183239; called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 11/289 reads (4%) | called by muse, mutect2
- LINC02843 | n.164del | RNA (DEL) | VAF 60/373 reads (16%) | called by mutect2, pindel, varscan2
- ZNF174 | c.*3G>C | 3'UTR (SNP) | VAF 42/163 reads (26%) | called by muse, mutect2, varscan2
